Somatic mutation profile of tumor specimen TCGA-17-Z002-01A (aliquot TCGA-17-Z002-01A-01W-0746-08) from TCGA case TCGA-17-Z002, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fde69fb5-1fd2-47b4-99c0-8bbcc4a13ba9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z002-11A (Solid Tissue Normal), aliquot TCGA-17-Z002-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3d46d37-7d15-4ba6-b2c6-9033fe4f3960

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAGE1 | c.1483G>A p.E495K (on ENST00000512086; = p.E359K on NM_205864.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV57075658; called by muse, mutect2, varscan2
- MFSD9 | c.1326dup p.S443Qfs*22 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs769987847; called by mutect2, varscan2
- NCOR2 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs866912317; called by muse, mutect2
- OXCT2 | c.767dup p.E257Rfs*7 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | catalogued as rs756942160; called by pindel, varscan2
- FMNL1 | c.1935G>C p.L645F | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.823); called by muse, mutect2
- GBF1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.038); called by muse, mutect2
- RASGRF1 | c.3148G>C p.D1050H | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- SNTG1 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
